Somatic mutation profile of tumor specimen 3d3e1888-d67e-4c69-ba83-112d0f (aliquot 3d3e1888-d67e-4c69-ba83-112d0f_D6) from CPTAC case 04OV005, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IV.
Specimen 3d3e1888-d67e-4c69-ba83-112d0f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49a54359-52bd-45c0-b7c8-90486f13c0c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen cade384a-f9d2-4e3b-9aa5-a0e64e (Blood Derived Normal), aliquot cade384a-f9d2-4e3b-9aa5-a0e64e_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7e00045-912a-4b03-a129-899c8a3e4aed

The open-access MAF lists 78 somatic variants for this specimen: 49 protein-altering or splice-affecting, 21 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 21, Intron 4, Splice Region 3, Splice Site 2, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRSK1 | c.1081T>C p.Y361H | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as rs1568986818; called by muse, mutect2, varscan2
- BSN | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.805); catalogued as rs1438104628; called by muse, mutect2
- C1RL | c.490+3G>C | Splice Region (SNP) | VAF 156/902 reads (17%) | catalogued as rs199564161; called by muse, mutect2, varscan2
- C7 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.643); catalogued as rs1313401268, COSV100496758; called by muse, mutect2, varscan2
- CSMD1 | c.1958G>A p.G653D (on ENST00000520002; = p.G652D on NM_033225.6) | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772452238; called by muse, mutect2, varscan2
- GALNT16 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV61887264; called by muse, mutect2, varscan2
- GRIK3 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557709492; called by muse, mutect2, varscan2
- HTR4 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | PolyPhen possibly damaging (0.81); catalogued as rs1159433696; called by muse, mutect2, varscan2
- ITPR2 | c.6068T>A p.L2023Q | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV67268052; called by muse, mutect2, varscan2
- JCAD | c.279G>A p.A93= | Splice Region (SNP) | VAF 9/87 reads (10%) | catalogued as rs185354868; called by muse, mutect2, varscan2
- KANK2 | c.1903G>A p.D635N (on ENST00000586659 / NM_001379562.1; = p.D643N on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.715); catalogued as rs756897734; called by muse, mutect2, varscan2
- KDM8 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149728125, COSV53729326; called by muse, mutect2
- MEX3A | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs781221338; called by muse, mutect2, varscan2
- NGB | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs978532025; called by muse, mutect2, varscan2
- PCGF1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1197266515; called by muse, mutect2, varscan2
- PLXNA4 | c.3766G>A p.V1256M | Missense Mutation (SNP) | VAF 518/956 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58104834; called by muse, mutect2, varscan2
- SLC2A4 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 470/860 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs768365925, COSV50300355; called by muse, mutect2, varscan2
- SLC5A1 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.714); catalogued as rs112120460; called by mutect2, varscan2
- SYN2 | c.747G>C p.Q249H | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55139230; called by muse, mutect2
- SYNCRIP | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs775682411; called by mutect2, varscan2
- TP53 | c.721del p.S241Pfs*6 | Frame Shift Del (DEL) | VAF 128/298 reads (43%) | catalogued as CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; called by mutect2, pindel, varscan2
- VWF | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 46/942 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771947987; called by muse, mutect2
- WNT5A | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99225077; called by muse, mutect2, varscan2
- AQP12B | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ATRX | c.370+1del p.X124_splice | Splice Site (DEL) | VAF 22/173 reads (13%) | called by mutect2, pindel, varscan2
- C2orf81 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CATSPER4 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCN4 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- CES4A | c.556C>A p.R186S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- CREBBP | c.4299T>A p.Y1433* | Nonsense Mutation (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- CXXC1 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DDX43 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH7 | c.10083+1G>T p.X3361_splice | Splice Site (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- FAM20C | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- FKBP1C | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- GARS1 | c.1565G>T p.C522F | Missense Mutation (SNP) | VAF 40/431 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- KRT14 | c.1323G>T p.V441= | Splice Region (SNP) | VAF 35/209 reads (17%) | called by muse, mutect2, varscan2
- OR5M10 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OS9 | c.892G>C p.G298R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- PCNT | c.7723A>G p.K2575E | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RADX | c.2134T>A p.F712I | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by mutect2, varscan2
- RBM6 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- RNF148 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- SCN8A | c.1810C>G p.P604A | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPINDOC | c.1064G>C p.G355A | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ULK4 | c.1486G>C p.A496P | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- WDR83OS | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ZMIZ1 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF266 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS12 | c.3687C>T p.S1229= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as rs555561274, COSV61266250; called by muse, mutect2, varscan2
- ADGRL1 | c.2670C>T p.T890= (on ENST00000340736 / NM_001008701.3; = p.T885= on NM_014921.5) | Silent (SNP) | VAF 52/399 reads (13%) | catalogued as rs372577340; called by muse, mutect2, varscan2
- ASAP2 | c.249C>T p.G83= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as rs369806962; called by muse, mutect2, varscan2
- CAV1 | c.285G>A p.T95= | Silent (SNP) | VAF 30/344 reads (9%) | catalogued as rs200894208; ClinVar: likely benign; called by muse, mutect2
- CEP295 | c.3996A>G p.Q1332= | Silent (SNP) | VAF 25/146 reads (17%) | called by muse, varscan2
- DIP2C | c.2415C>T p.N805= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as rs768099475, COSV99791772; called by muse, mutect2, varscan2
- FCGBP | c.1371G>T p.V457= | Silent (SNP) | VAF 21/354 reads (6%) | catalogued as rs764809562; called by muse, mutect2
- FPR1 | c.738C>T p.V246= | Silent (SNP) | VAF 34/217 reads (16%) | catalogued as rs148898220; called by muse, mutect2, varscan2
- INPP5E | c.108G>C p.A36= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1478815621; called by muse, mutect2, varscan2
- JAG2 | c.3135G>A p.A1045= | Silent (SNP) | VAF 61/453 reads (13%) | catalogued as rs754261690; called by muse, mutect2, varscan2
- LAMA5 | c.10323G>T p.T3441= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99440683; called by mutect2, varscan2
- MIEF2 | c.552C>T p.D184= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs367578636; called by mutect2, varscan2
- MUC17 | c.4443C>T p.D1481= | Silent (SNP) | VAF 13/134 reads (10%) | called by muse, varscan2
- PCDHGA11 | c.1704C>G p.L568= | Silent (SNP) | VAF 37/312 reads (12%) | called by muse, mutect2, varscan2
- PLOD1 | c.456G>A p.L152= | Silent (SNP) | VAF 29/194 reads (15%) | called by muse, mutect2, varscan2
- PPP6R1 | c.534G>T p.L178= | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- PTX3 | c.912G>A p.E304= | Silent (SNP) | VAF 28/331 reads (8%) | called by muse, mutect2
- SMG1 | c.9411C>G p.L3137= | Silent (SNP) | VAF 97/351 reads (28%) | catalogued as COSV67170777; called by muse, mutect2, varscan2
- TMEM121B | c.1131G>C p.P377= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100083289; called by muse, mutect2, varscan2
- TNN | c.1638C>T p.T546= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs752011838, COSV99512726; called by muse, mutect2, varscan2
- VCPIP1 | c.99G>T p.S33= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs774673882; called by mutect2, varscan2
- AGAP1 | c.1646-21729G>A | Intron (SNP) | VAF 10/86 reads (12%) | catalogued as rs961116549; called by muse, mutect2, varscan2
- ATRX | c.-40C>T | 5'UTR (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- LINC02868 | n.323G>C | RNA (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- MAN2B1 | c.436+16G>T | Intron (SNP) | VAF 149/360 reads (41%) | catalogued as COSV54417439; called by muse, mutect2, varscan2
- MSLNL | c.37+1309C>G | Intron (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- SERPINB13 | chr18:63604014 G>A | 3'Flank (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- TMEM71 | c.40+47G>T | Intron (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- TTYH1 | c.*33C>T | 3'UTR (SNP) | VAF 34/131 reads (26%) | catalogued as rs568496543; called by muse, mutect2, varscan2
